Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8108, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8108-01A (Primary Tumor).

report

Microscopic

Sections demonstrate a moderately hypercellular glial neoplasm which diffusely infiltrates both gray and white matter. The majority of the tumor cells demonstrate either perinuclear halos or gemistocytic cytoplasm. The minority component with possible fibrillary astrocytic phenotype is also seen. Nearly all tumor cells lack overt processes and have round nuclei with mild to moderate atypia. Mitotic figures are not seen. There is no microvascular proliferation or necrosis.

Addendum

Scattered MIB-1 reactive cells are present throughout the tumor. A labeling index of 4.4% is calculated.

Diagnosis

Consistent with low grade oligodendroglioma

Source: NCI Genomic Data Commons file a59147b8-2c4a-4bc5-b065-dde7e23165a8 (TCGA-HT-8108.8E2E0A3B-AFD5-4077-B95F-DDC7014C08CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).